Somatic mutation profile of tumor specimen TARGET-50-PAJNNC-01A (aliquot TARGET-50-PAJNNC-01A-01D) from TARGET case TARGET-50-PAJNNC, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.8 years (281 days).
Specimen TARGET-50-PAJNNC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36dc815d-bba5-4945-9904-3287eb135392.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNNC-11A (Solid Tissue Normal), aliquot TARGET-50-PAJNNC-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5131977-d04b-47bb-95a0-12af6759232f

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMZ1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs999550677, COSV56689037; called by muse, mutect2, varscan2
- CCDC105 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs531540932; called by muse, mutect2, varscan2
- BRINP2 | c.633dup p.L212Afs*27 | Frame Shift Ins (INS) | VAF 58/293 reads (20%) | called by mutect2, pindel, varscan2
- CD36 | c.360del p.I121Sfs*36 | Frame Shift Del (DEL) | VAF 39/125 reads (31%) | called by mutect2, pindel, varscan2
